Surgical pathology report (de-identified scan), TCGA case TCGA-5M-AAT5, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Sao Paulo, specimen TCGA-5M-AAT5-01A (Primary Tumor).

Date:

SPECIMEN: sigmoid colon

PROCEDURE: rectosigmoidectomy

MACROSCOPY

- Segment of colon, measuring 17.0 cm in length and 3.0 in diameter.
- Vegetative lesion, with elevated borders, measuring 5.0 x 4.5 cm, located in the mucosa 1.8 cm from the nearest surgical margin.
- The lesion penetrates the full thickness of the wall, infiltrating the adjacent fat tissue.
- Two separated fragments of unlabeled colonic mucosa: one circular measuring 2.3 cm in diameter and 0.7 cm in length, the other irregular, measuring 1.5 x 0.9 x 0.4 cm.
- A number of lymph nodes dissected from the adjacent fat tissue.

MICROSCOPIC EXAMINATION

- Moderately differentiated, invasive, tubular adenocarcinoma of the sigmoid colon;
- Microscopic tumor extension: tumor penetrates the full thickness of the colonic wall, extending to the pericolic fat;
- Perineural invasion: present;
- Surgical margins free of neoplastic involvement;
- Circular fragment consisting of colonic wall, which displays no signs of neoplastic involvement;
- Irregular fragment consisting of fragment of adenocarcinoma;
- Number of lymph nodes examined: 13;
- Number of lymph nodes involved: 04;
- Stage (TNM): pT3 pN2

PATHOLOGISTS

ICD-O 3
MLF Adenocarcinoma NOS 8140/3
path Adenocarcinoma, tubular 8211/3
Site: Sigmoid colon C18:7
JF 5/21/14

Source: NCI Genomic Data Commons file b46452a0-d1c5-4d00-960e-0320b4c72122 (TCGA-5M-AAT5.AA3CF932-9666-4280-9F3E-5CFA523CEC4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).